Somatic mutation profile of tumor specimen TCGA-AA-3526-01A (aliquot TCGA-AA-3526-01A-02D-1953-10) from TCGA case TCGA-AA-3526, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 57.8 years (21,123 days).
Specimen TCGA-AA-3526-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48de9723-eaaf-4b6b-a07a-3c9ccb1fa3f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3526-11A (Solid Tissue Normal), aliquot TCGA-AA-3526-11A-01D-1554-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49e0a151-9f01-4a4a-a5c4-7a30bd921c2b

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 19, Silent 7, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 18/72 reads (25%) | hotspot (GDC flag); called by pindel, varscan2
- ADAMTS10 | c.1213G>T p.V405L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV54353736; called by muse, mutect2, varscan2
- CBFA2T3 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748831977, COSV99242041; called by muse, mutect2, varscan2
- CD1E | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 83/222 reads (37%) | catalogued as COSV100937024; called by muse, mutect2, varscan2
- CEP19 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56361484; called by muse, mutect2, varscan2
- CIAO3 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 127/400 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284978; called by muse, mutect2, varscan2
- CLCN2 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs373554707; called by muse, mutect2, varscan2
- COL22A1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as rs755559463, COSV57348684; called by muse, mutect2, varscan2
- DPYSL4 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 140/387 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1378531905, COSV58307562; called by muse, mutect2, varscan2
- GCN1 | c.6346G>A p.V2116I | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100325526; called by muse, mutect2, varscan2
- GRB10 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs778877926, COSV100240690; called by muse, mutect2, varscan2
- GUCY2D | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99644083; called by muse, mutect2
- GUCY2D | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.036); catalogued as COSV99644084; called by muse, varscan2
- LHX3 | c.146G>A p.R49H (on ENST00000371748 / NM_178138.6; = p.R54H on NM_014564.5) | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1185140701, COSV100871252; called by muse, mutect2, varscan2
- MSC | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs753728260, COSV100335782; called by muse, mutect2, varscan2
- NOS1 | c.2747T>C p.I916T | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV100500853; called by muse, mutect2, varscan2
- PCDHA2 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.287); catalogued as COSV65365430; called by muse, mutect2, varscan2
- PCDHA8 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.39); catalogued as COSV65337750; called by muse, mutect2, varscan2
- RTKN | c.1633C>T p.R545W (on ENST00000272430 / NM_001015055.2; = p.R532W on NM_033046.2) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as rs374992298; called by muse, mutect2, varscan2
- TMEM214 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.095); catalogued as COSV99476289; called by muse, mutect2
- ZNF831 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs1398530461, COSV100925865; called by muse, mutect2, varscan2
- ANKRD53 | c.62dup p.E22Rfs*29 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- ARHGDIG | c.654C>T p.C218= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs758312207, COSV99250020; called by muse, varscan2
- CFAP298-TCP10L | c.81C>A p.L27= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99267418; called by muse, mutect2, varscan2
- CPSF1 | c.1524G>A p.K508= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV100574642; called by muse, mutect2, varscan2
- FAT1 | c.4287C>T p.V1429= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs772770463; called by muse, mutect2
- GUCY2D | c.1299G>A p.R433= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV99644085; called by muse, varscan2
- PLPP7 | c.474G>A p.T158= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs950770151, COSV100953150; called by muse, mutect2
- PPP1R16B | c.237C>T p.N79= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV55382231; called by muse, varscan2
